Somatic mutation profile of tumor specimen TCGA-DB-A64P-01A (aliquot TCGA-DB-A64P-01A-11D-A29Q-08) from TCGA case TCGA-DB-A64P, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 40.9 years (14,936 days).
Specimen TCGA-DB-A64P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efd7f7fd-c803-4602-b3e2-2d1f1797ffa0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A64P-10A (Blood Derived Normal), aliquot TCGA-DB-A64P-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e595160d-003c-47d7-a081-f28ba9443e60

The open-access MAF lists 26 somatic variants for this specimen: 24 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 20, Nonsense Mutation 2, Silent 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 27/91 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50554428; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 30/57 reads (53%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CXCL13 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs150188610, COSV54493830; called by muse, mutect2, varscan2
- FAT2 | c.2197C>T p.P733S | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs1001969191, COSV55830091; called by muse, mutect2, varscan2
- ITGAX | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 44/270 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs200458998, COSV51650268; called by muse, mutect2, varscan2
- JUP | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373434456; called by muse, mutect2, varscan2
- KDM5B | c.1708C>T p.R570* | Nonsense Mutation (SNP) | VAF 41/81 reads (51%) | catalogued as rs367833330; called by muse, mutect2, varscan2
- KLF14 | c.763T>G p.F255V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60589124; called by muse, mutect2, varscan2
- MFSD12 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV62597226, COSV62598487; called by muse, mutect2
- NEB | c.8383A>G p.K2795E | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1488927834, COSV51462381; called by muse, varscan2
- NR5A2 | c.485G>A p.R162H (on ENST00000367362 / NM_205860.3; = p.R116H on NM_003822.5) | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751202522, COSV52646005; called by muse, mutect2, varscan2
- OR2G6 | c.263A>T p.K88I | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV58575932; called by muse, mutect2, varscan2
- PCDHA5 | c.125C>A p.T42N | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); catalogued as rs782025339, COSV65357039, COSV65359270; called by muse, mutect2, varscan2
- PLEK | c.266G>C p.R89T | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52254098; called by muse, mutect2
- RAD52 | c.1073T>A p.L358* | Nonsense Mutation (SNP) | VAF 16/119 reads (13%) | catalogued as COSV57274645; called by muse, mutect2, varscan2
- STEAP1 | c.583T>A p.W195R | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.93); catalogued as COSV51883129; called by muse, mutect2
- STON1 | c.1370C>A p.T457N | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.867); catalogued as rs776598075, COSV59138742; called by muse, mutect2, varscan2
- SYT7 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs382505, COSV55654064, COSV55659794; called by muse, mutect2, varscan2
- TMEM132B | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1342117104, COSV54753211; called by muse, mutect2, varscan2
- ZNF266 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV63223319; called by muse, mutect2, varscan2
- LRRC37A2 | c.4851_4859+1del | Frame Shift Del (DEL) | VAF 23/94 reads (24%) | called by mutect2, varscan2
- RLF | c.1866A>T p.K622N | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2
- TPTE | c.770A>G p.Q257R (on ENST00000618007 / NM_199261.4; = p.Q239R on NM_199259.4) | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WNT8A | c.437_438del p.F146Cfs*54 | Frame Shift Del (DEL) | VAF 19/188 reads (10%) | called by mutect2, pindel, varscan2
- ARHGEF4 | c.1008C>A p.I336= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV58130650; called by muse, mutect2, varscan2
- MUC16 | c.9045T>C p.T3015= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as rs780348288, COSV67496268; called by muse, mutect2, varscan2
